Gene-level copy-number profile of tumor specimen TCGA-MP-A4T8-01A from TCGA case TCGA-MP-A4T8, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.6 years (25,069 days).
Specimen TCGA-MP-A4T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1da20181-a246-49e3-a0bd-8542a96b3243.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4T8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6250ba61-37fa-4e1e-8038-211a1e982df7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 59; copy number 2: 16,708; copy number 3: 17,479; copy number 4: 17,887; copy number 5: 5,857; copy number 6: 182; copy number 7: 96; copy number 8: 190; copy number 9: 501; copy number 10: 405; copy number 11: 66; copy number 13: 51; copy number 14: 8; copy number 15: 55; copy number 17: 41; copy number 18: 20; copy number 19: 47; copy number 20: 4; copy number 21: 36; copy number 22: 1; copy number 24: 40; copy number 30: 70; copy number 41: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4T8-01A-11D-A24O-01): tumor purity 0.59, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,245,603–133,257,207, 1 gene: TMEM108-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,358 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,155,116, 476 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:67,173,511–74,823,313, 124 genes, copy number 10–18 (within-gene range 2–23) (broad region; genes not listed).
- chr8:79,259,402–81,924,348, 70 genes, copy number 10 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 10: LINC02839.
- chr8:83,912,713–84,921,844, 6 genes, copy number 11 (within-gene range 6–11): AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2.
- chr8:87,540,835–87,755,718, 1 gene, copy number 11 (within-gene range 6–11): AF121898.1.
- chr8:87,788,562–111,757,710, 386 genes, copy number 10–22 (broad region; genes not listed).
- chr8:113,376,669–131,144,948, 228 genes, copy number 11–41 (broad region; genes not listed).
- chr8:131,712,512–132,848,807, 13 genes, copy number 13: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1.
- chr8:133,771,409–133,814,537, 1 gene, copy number 13 (within-gene range 4–13): AC133634.1.
- chr8:133,786,093–134,713,049, 11 genes, copy number 13 (within-gene range 4–13): AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr8:134,792,020–135,742,495, 12 genes, copy number 17: AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:136,237,236–136,295,232, 1 gene, copy number 14 (within-gene range 2–14): AC023781.1.
- chr8:137,424,904–137,698,467, 3 genes, copy number 14: ZYXP1, AC105213.1, AC110053.1.
- chr16:72,665,123–72,822,781, 4 genes, copy number 9: AC004943.2, RNU7-90P, KRT18P18, AC004943.3.
- chr16:72,805,998–73,233,970, 10 genes, copy number 9: AC004943.1, RNU7-71P, AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5, AC116667.2, AC140912.1.
- chr16:90,019,629–90,222,851, 11 genes, copy number 9: GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
